Somatic mutation profile of tumor specimen TARGET-10-PATWIJ-09A (aliquot TARGET-10-PATWIJ-09A-01D) from TARGET case TARGET-10-PATWIJ, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.2 years (5,187 days).
Specimen TARGET-10-PATWIJ-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d7409da4-a5da-438c-ac66-036acfcd6fab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATWIJ-10A (Blood Derived Normal), aliquot TARGET-10-PATWIJ-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aa8f1c51-194b-430e-a01a-9d3ab9e9984b

The open-access MAF lists 37 somatic variants for this specimen: 21 protein-altering or splice-affecting, 9 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 9, Frame Shift Ins 3, 3'UTR 2, 5'UTR 2, Nonsense Mutation 1, RNA 1, In Frame Ins 1, 5'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1436G>T p.R479L (on ENST00000281708 / NM_001349798.2; = p.R399L on NM_018315.5) | Missense Mutation (SNP) | VAF 101/210 reads (48%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs866987936, COSV55890822, COSV55894913, COSV55899054; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AHNAK | c.865G>C p.V289L | Missense Mutation (SNP) | VAF 71/150 reads (47%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.974); catalogued as COSV57229352; called by muse, mutect2, varscan2
- CADPS2 | c.1170G>T p.M390I | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.885); catalogued as COSV57352508; called by muse, mutect2
- CFAP47 | c.7790T>G p.I2597S | Missense Mutation (SNP) | VAF 35/36 reads (97%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV66220498; called by muse, mutect2, varscan2
- CLEC2A | c.325G>A p.A109T | Missense Mutation (SNP) | VAF 123/250 reads (49%) | SIFT tolerated (0.51); PolyPhen benign (0.069); catalogued as rs1249291070, COSV60274408; called by muse, mutect2, varscan2
- COL6A6 | c.4748C>T p.P1583L | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.575); catalogued as rs1293474518, COSV62027988, COSV62036516; called by muse, mutect2, varscan2
- FCGBP | c.490G>A p.G164S | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as rs138776563; called by muse, mutect2
- MYH6 | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV62449475; called by muse, mutect2
- NFIA | c.52G>A p.A18T | Missense Mutation (SNP) | VAF 66/162 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64543829; called by muse, mutect2, varscan2
- NOTCH1 | c.4817_4818insTGGGGGAGCGTTGACTGGGTTGGG p.F1606_K1607insGGALTGLG | In Frame Ins (INS) | VAF 11/34 reads (32%) | catalogued as COSV53027782, COSV53042984, COSV53043409, COSV53046232, COSV53074253, COSV53074374, COSV53075070, COSV53075246, COSV53075642, COSV53081693, COSV53092183, COSV53095779, COSV53096923, COSV53096963, COSV53097268, COSV5…; called by mutect2, pindel
- PDS5B | c.2170dup p.R724Pfs*16 | Frame Shift Ins (INS) | VAF 92/197 reads (47%) | catalogued as rs746601412; called by mutect2, varscan2
- PSMD4 | c.243G>C p.K81N | Missense Mutation (SNP) | VAF 54/109 reads (50%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs150267583, COSV64394060; called by muse, mutect2, varscan2
- SASH1 | c.3196G>A p.E1066K | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.644); catalogued as rs747556320, COSV66565504; called by muse, mutect2, varscan2
- SNCAIP | c.1613C>T p.T538M | Missense Mutation (SNP) | VAF 12/177 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.791); catalogued as rs147147229; called by muse, mutect2
- STAT5B | c.2135T>A p.V712E | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.04); catalogued as COSV53185111; called by muse, mutect2
- SUOX | c.1298G>A p.R433Q | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs201249214; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TENM3 | c.5158C>T p.P1720S | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as COSV69318600; called by muse, mutect2, varscan2
- GLRA3 | c.690C>G p.Y230* | Nonsense Mutation (SNP) | VAF 6/136 reads (4%) | called by muse, mutect2
- PHF6 | c.655_658dup p.E220Gfs*5 (on ENST00000332070 / NM_032458.3; = p.E221Gfs*5 on NM_032335.3) | Frame Shift Ins (INS) | VAF 58/66 reads (88%) | called by mutect2, pindel, varscan2
- RAB26 | c.518T>C p.M173T | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.743); called by muse, varscan2
- SPATA6 | c.506dup p.L169Ffs*5 | Frame Shift Ins (INS) | VAF 26/60 reads (43%) | called by mutect2, pindel, varscan2
- ATP9B | c.1659C>T p.N553= | Silent (SNP) | VAF 94/175 reads (54%) | catalogued as rs148663973; called by muse, mutect2, varscan2
- HRNR | c.333A>G p.E111= | Silent (SNP) | VAF 7/149 reads (5%) | called by muse, mutect2
- KLHL38 | c.273C>T p.Y91= | Silent (SNP) | VAF 51/91 reads (56%) | catalogued as rs1213606509; called by muse, mutect2, varscan2
- LRP1B | c.4683G>A p.K1561= | Silent (SNP) | VAF 26/72 reads (36%) | called by muse, mutect2, varscan2
- PSG2 | c.891G>C p.G297= | Silent (SNP) | VAF 68/143 reads (48%) | called by muse, mutect2, varscan2
- PTPRT | c.1782C>T p.Y594= | Silent (SNP) | VAF 15/81 reads (19%) | catalogued as rs377291418; ClinVar: likely benign; called by muse, mutect2, varscan2
- SNX25 | c.1782G>A p.S594= | Silent (SNP) | VAF 30/60 reads (50%) | catalogued as rs372010830; called by muse, mutect2, varscan2
- TDRP | c.246A>G p.A82= | Silent (SNP) | VAF 44/134 reads (33%) | catalogued as COSV60706951; called by muse, mutect2, varscan2
- ZNF490 | c.957G>A p.T319= | Silent (SNP) | VAF 73/121 reads (60%) | catalogued as rs771643755, COSV61007798; called by muse, mutect2, varscan2
- CDH15 | chr16:89168670 C>T | 5'Flank (SNP) | VAF 25/62 reads (40%) | called by muse, mutect2, varscan2
- EGFLAM | c.-67G>T | 5'UTR (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2
- KCNH4 | c.-4G>A | 5'UTR (SNP) | VAF 5/38 reads (13%) | called by muse, mutect2
- MSL1 | c.1424-11T>C | Intron (SNP) | VAF 23/40 reads (58%) | catalogued as rs760108939; called by muse, varscan2
- PPP1R8 | c.*1051A>C | 3'UTR (SNP) | VAF 18/50 reads (36%) | called by muse, mutect2, varscan2
- RNASEH2B | c.*11G>A | 3'UTR (SNP) | VAF 42/102 reads (41%) | catalogued as rs1197025634; called by muse, mutect2, varscan2
- TUBBP1 | n.620G>A | RNA (SNP) | VAF 10/265 reads (4%) | called by muse, mutect2
